Somatic mutation profile of tumor specimen TARGET-10-PAPFBX-09A (aliquot TARGET-10-PAPFBX-09A-01D) from TARGET case TARGET-10-PAPFBX, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.4 years (1,624 days).
Specimen TARGET-10-PAPFBX-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31492130-3e1f-469f-b020-479f33cdacae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPFBX-14A (Bone Marrow Normal), aliquot TARGET-10-PAPFBX-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a66960c8-d2b2-4a99-a47f-02e480c37576

The open-access MAF lists 11 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, Nonsense Mutation 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C4orf54 | c.1939C>T p.R647W | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs758405101; called by muse, mutect2, varscan2
- PCDHA5 | c.1850C>T p.A617V | Missense Mutation (SNP) | VAF 19/41 reads (46%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.014); catalogued as COSV65352116; called by muse, mutect2, varscan2
- PSAPL1 | c.754G>C p.G252R | Missense Mutation (SNP) | VAF 42/140 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.169); catalogued as rs774177996; called by muse, mutect2, varscan2
- PTPRG | c.1082C>T p.T361M | Missense Mutation (SNP) | VAF 10/21 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs751693280, COSV55654273; called by muse, mutect2, varscan2
- WIF1 | c.946G>A p.A316T | Missense Mutation (SNP) | VAF 25/39 reads (64%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1240436246; called by muse, mutect2, varscan2
- ZHX3 | c.1960C>T p.R654* | Nonsense Mutation (SNP) | VAF 51/100 reads (51%) | catalogued as rs1216531405, COSV58384779; called by muse, mutect2, varscan2
- ZNF391 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.02); catalogued as rs372035777; called by muse, mutect2, varscan2
- ANKFN1 | c.3249C>T p.S1083= (on ENST00000653862; = p.S936= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 61/188 reads (32%) | catalogued as rs1200772561; called by muse, mutect2, varscan2
- DAAM2 | c.1053C>T p.I351= | Silent (SNP) | VAF 19/91 reads (21%) | catalogued as rs376401177; called by muse, mutect2, varscan2
- TGIF2LX | c.633C>T p.H211= | Silent (SNP) | VAF 51/175 reads (29%) | catalogued as rs776091366, COSV52213264; called by muse, mutect2, varscan2
- GDI1 | c.991+26C>A | Intron (SNP) | VAF 28/116 reads (24%) | called by muse, mutect2, varscan2
